Gene-level copy-number profile of tumor specimen TCGA-SI-AA8B-01A from TCGA case TCGA-SI-AA8B, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 80.3 years (29,315 days).
Specimen TCGA-SI-AA8B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.110767f7-2d8c-4754-9958-6fce7b088378.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SI-AA8B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b2dc20fd-85b9-40a3-98f1-c5484204e533

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 3,080; copy number 2: 21,631; copy number 3: 16,174; copy number 4: 7,877; copy number 5: 8,017; copy number 6: 2,417; copy number 7: 325; copy number 8: 144.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SI-AA8B-01A-11D-A386-01): tumor purity 0.88, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 148 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:46,717,423–48,037,968, 10 genes (within-gene range 0–1): AL359880.1, ESD, HTR2A, HTR2A-AS1, GNG5P5, RN7SL700P, SUCLA2, NAP1L4P3, RPL27AP8, AL138962.1.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,429,269–50,125,720, 44 genes: Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,387,158, 7 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr16:34,266,041–35,912,516, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,691 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–178,921,841, 4,042 genes, copy number 5 (broad region; genes not listed).
- chr1:181,174,484–184,672,166, 69 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:184,790,724–186,681,446, 41 genes, copy number 5: NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR.
- chr3:173,396,284–174,286,644, 3 genes, copy number 6 (within-gene range 4–6): NLGN1, AC092967.1, NLGN1-AS1.
- chr4:53,377,839–54,859,241, 25 genes, copy number 5 (within-gene range 3–5): AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358.
- chr4:56,907,876–136,553,739, 1,038 genes, copy number 5 (broad region; genes not listed).
- chr5:2,712,591–39,889,059, 537 genes, copy number 6–8 (broad region; genes not listed).
- chr7:1,152,071–2,242,215, 23 genes, copy number 6 (within-gene range 4–6): ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655.
- chr7:3,264,032–3,302,452, 1 gene, copy number 6 (within-gene range 4–6): SDK1-AS1.
- chr7:3,337,889–3,338,601, 1 gene, copy number 6: AC092427.1.
- chr7:6,497,462–25,500,443, 256 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:27,361,591–29,514,667, 28 genes, copy number 6 (within-gene range 4–6): AC004009.1, AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1, TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1, RNU6-979P, JAZF1-AS1, PPIAP80, CREB5, AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4.
- chr7:34,124,948–34,299,012, 3 genes, copy number 7: AC007350.1, AC009262.1, RNU6-438P.
- chr7:38,977,909–39,493,095, 1 gene, copy number 6 (within-gene range 4–6): POU6F2.
- chr7:39,329,003–40,115,943, 23 genes, copy number 6: SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1.
- chr8:150,584–56,776,874, 1,116 genes, copy number 5 (broad region; genes not listed).
- chr13:23,730,189–23,889,400, 2 genes, copy number 5 (within-gene range 4–5): MIPEP, MTCO3P2.
- chr13:84,867,514–114,337,626, 404 genes, copy number 5–8 (broad region; genes not listed).
- chr15:19,878,555–48,963,919, 895 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:59,132,434–59,372,871, 1 gene, copy number 6 (within-gene range 4–6): MYO1E.
- chr15:59,206,843–101,933,350, 1,101 genes, copy number 5–8 (broad region; genes not listed).
- chr17:68,152,776–83,095,122, 509 genes, copy number 5 (broad region; genes not listed).
- chr18:4,264,602–5,004,537, 5 genes, copy number 6 (within-gene range 2–6): DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14.
- chr18:7,076,817–7,461,135, 5 genes, copy number 5: AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1.
- chr18:7,741,310–7,815,730, 2 genes, copy number 5: AP000897.2, AP000897.1.
- chr20:30,214,765–48,849,458, 523 genes, copy number 5–6 (broad region; genes not listed).
- chr20:53,421,199–54,070,594, 13 genes, copy number 7: PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.
- chr20:61,717,506–62,447,677, 24 genes, copy number 5: AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1.

Autosomal genes at a single copy (total copy number 1): 3,080. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
